Gene-level copy-number profile of tumor specimen C3N-03488-03 from CPTAC case C3N-03488, project CPTAC-3 (Other and ill-defined sites — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-03488-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Sinus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43400ba5-92aa-4567-baa3-279f2c90ee66.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03488-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/15cebcb3-0cb8-4cf0-bff7-2dc21ecb62df

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 570; copy number 2: 8,822; copy number 3: 21,427; copy number 4: 13,525; copy number 5: 7,973; copy number 6: 1,583; copy number 7: 3,739; copy number 8: 814; copy number 9: 105; copy number 10: 11; copy number 11: 57; copy number 12: 1; copy number 13: 9; copy number 14: 25; copy number 15: 15; copy number 16: 4; copy number 23: 10; copy number 26: 14; copy number 29: 31; copy number 31: 15; copy number 33: 35; copy number 40: 2; copy number 44: 3; copy number 57: 7; copy number 65: 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–23,438,700, 60 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:41,890,314–42,499,134, 14 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:42,830,337–42,950,827, 2 genes (within-gene range 0–3): ANKRD20A7P, RNU6-599P.
- chr9:64,465,463–64,498,745, 5 genes: CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr17:18,411,159–18,551,705, 14 genes (within-gene range 0–2): LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,898 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,824,235–198,123,232, 1,089 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr4:105,959–202,303, 3 genes, copy number 7 (within-gene range 4–7): AC253576.1, ZNF718, AC253576.2.
- chr5:16,615,926–16,681,905, 1 gene, copy number 7 (within-gene range 6–7): AC024588.1.
- chr5:16,661,907–28,287,807, 133 genes, copy number 7 (broad region; genes not listed).
- chr5:51,055,353–52,959,209, 22 genes, copy number 9–14 (within-gene range 4–14): RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1.
- chr7:45,769,105–50,565,405, 59 genes, copy number 14–65: GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1.
- chr7:52,891,837–52,897,807, 1 gene, copy number 10: SGO1P2.
- chr7:54,621,025–55,433,742, 12 genes, copy number 40–57: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr8:40,104,169–41,578,421, 23 genes, copy number 7–11 (within-gene range 6–11): AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4.
- chr8:60,185,412–145,066,685, 1,289 genes, copy number 7–8 (broad region; genes not listed).
- chr11:64,606,174–71,997,597, 349 genes, copy number 7–33 (broad region; genes not listed).
- chr13:71,437,966–72,706,123, 12 genes, copy number 10–11: DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P.
- chr13:72,782,133–79,166,885, 83 genes, copy number 7–16 (within-gene range 5–16) (broad region; genes not listed).
- chr13:79,804,418–81,691,072, 17 genes, copy number 7–13: LINC01038, LINC00382, AL158064.1, LINC01080, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr14:36,320,753–43,596,683, 79 genes, copy number 7–9 (broad region; genes not listed).
- chr14:74,239,449–106,879,812, 927 genes, copy number 7–9 (broad region; genes not listed).
- chr17:22,519,617–28,196,381, 58 genes, copy number 7: MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2, AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22.
- chr19:28,435,388–30,957,192, 45 genes, copy number 8: AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:37,007,857–39,508,481, 118 genes, copy number 7 (broad region; genes not listed).
- chr19:53,732,981–55,545,543, 170 genes, copy number 7 (broad region; genes not listed).
- chr20:17,887,363–20,360,703, 58 genes, copy number 7: AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P.
- chr20:31,341,371–36,894,235, 205 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:51,902,291–60,653,784, 145 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
